Gene-level copy-number profile of tumor specimen TCGA-KN-8433-01A from TCGA case TCGA-KN-8433, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 46.8 years (17,108 days).
Specimen TCGA-KN-8433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.c74f3074-c901-49af-8a8e-4ab571561794.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KN-8433-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b34e306-66f5-4264-9741-de47d55d8e47

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2; copy number 3: 65; copy number 4: 29,827; copy number 5: 6,577; copy number 6: 174; copy number 7: 2,232; copy number 8: 19,865; copy number 9: 1,078.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KN-8433-01A-11D-2308-01): tumor purity 0.71, ploidy 1.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:138,215,986–138,218,491, 1 gene, copy number 9: PBOV1.
- chr16:63,935,778–66,335,138, 19 genes, copy number 9: AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, AC012325.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
